Somatic mutation profile of tumor specimen TARGET-10-PATJZK-09A (aliquot TARGET-10-PATJZK-09A-01D) from TARGET case TARGET-10-PATJZK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 18.7 years (6,843 days).
Specimen TARGET-10-PATJZK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e57359ba-0947-4f5a-a9e5-39284d613aa2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATJZK-10A (Blood Derived Normal), aliquot TARGET-10-PATJZK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25663cf1-1f5d-440f-b5e2-aed590a8b7c0

The open-access MAF lists 41 somatic variants for this specimen: 28 protein-altering or splice-affecting, 5 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 5, Intron 5, Splice Site 4, In Frame Ins 2, Splice Region 1, Frame Shift Del 1, Frame Shift Ins 1, RNA 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 47/129 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 48/114 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267606920, CM100127, COSV54736394, COSV54741067; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC100868.1 | c.932G>A p.S311N | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as COSV51847075; called by muse, mutect2, varscan2
- AC132217.2 | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated, low confidence (1); catalogued as rs758114081, COSV56098182; called by muse, mutect2
- ARHGEF11 | c.1217A>T p.E406V | Missense Mutation (SNP) | VAF 63/136 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV63814587; called by muse, mutect2, varscan2
- AVPR1A | c.970+2T>C p.X324_splice | Splice Site (SNP) | VAF 48/90 reads (53%) | catalogued as COSV54547462; called by muse, mutect2, varscan2
- DUSP15 | c.331G>A p.V111M (on ENST00000278979 / NM_001320479.1; = p.V114M on NM_080611.4) | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs531419522, COSV54065185; called by muse, mutect2, varscan2
- HHIP | c.498del p.E166Dfs*58 | Frame Shift Del (DEL) | VAF 72/212 reads (34%) | catalogued as COSV56842189; called by mutect2, pindel, varscan2
- ILK | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as rs759330457, COSV54991578; called by muse, mutect2, varscan2
- MYH8 | c.5473C>A p.L1825I | Missense Mutation (SNP) | VAF 97/215 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV67969453; called by muse, mutect2, varscan2
- NOL4 | c.538C>A p.P180T | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV52354855; called by muse, mutect2, varscan2
- NOTCH1 | c.4776_4777insGCC p.F1592_L1593insA | In Frame Ins (INS) | VAF 24/60 reads (40%) | catalogued as COSV53052993; called by mutect2, pindel, varscan2
- OR4C16 | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 142/301 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199938003, COSV58942583; called by muse, mutect2, varscan2
- PMPCA | c.1263+1_1263+2insGGAAGATGCA p.X421_splice | Splice Site (INS) | VAF 42/107 reads (39%) | catalogued as COSV65510384; called by mutect2, pindel*, varscan2*
- PPP1R26 | c.2290G>A p.G764S | Missense Mutation (SNP) | VAF 65/135 reads (48%) | SIFT tolerated (0.9); PolyPhen benign (0.011); catalogued as COSV63356534; called by muse, mutect2, varscan2
- RAD18 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as rs150523552; called by muse, mutect2, varscan2
- RASGRP2 | c.1046G>T p.S349I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV62449205; called by muse, mutect2, varscan2
- SNTB2 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.055); catalogued as COSV60350644; called by muse, mutect2, varscan2
- SPATA31E1 | c.3398G>A p.R1133H | Missense Mutation (SNP) | VAF 49/74 reads (66%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.735); catalogued as rs531419008, COSV57790676; called by muse, mutect2, varscan2
- SUFU | c.794A>G p.N265S | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.526); catalogued as COSV64015698; called by muse, mutect2, varscan2
- TTC16 | c.2401A>G p.S801G | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV60161640; called by muse, mutect2, varscan2
- TTC6 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.183); catalogued as rs1213070059; called by muse, mutect2, varscan2
- WT1 | c.1063-2A>C p.X355_splice | Splice Site (SNP) | VAF 20/38 reads (53%) | catalogued as CS086529, COSV60070765, COSV60071556, COSV60077344; called by muse, mutect2, varscan2
- ZMYM2 | c.2350C>T p.R784C | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746386044, COSV67036247; called by muse, mutect2, varscan2
- BAZ1A | c.1208_1209insGTGGAAGAGAACCA p.C404Wfs*18 | Frame Shift Ins (INS) | VAF 12/94 reads (13%) | called by mutect2, pindel
- CNOT3 | c.162delinsAGGAGACCCAAGGGAAGAGTCT p.K54_L55insGDPREES | In Frame Ins (INS) | VAF 12/45 reads (27%) | called by pindel, varscan2*
- NTRK1 | c.359+1G>C p.X120_splice | Splice Site (SNP) | VAF 35/76 reads (46%) | called by muse, mutect2, varscan2
- SNX7 | c.1123C>T p.L375= | Splice Region (SNP) | VAF 22/62 reads (35%) | called by muse, mutect2, varscan2
- AADACL4 | c.828C>T p.D276= | Silent (SNP) | VAF 73/159 reads (46%) | catalogued as rs760435668; called by muse, mutect2, varscan2
- EIF2AK4 | c.4617G>A p.P1539= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as rs199783641; called by muse, mutect2, varscan2
- MYO16 | c.5145G>A p.T1715= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as rs757251623; called by muse, mutect2, varscan2
- NGEF | c.936C>T p.S312= | Silent (SNP) | VAF 43/100 reads (43%) | catalogued as rs199543898, COSV99888040; called by muse, mutect2, varscan2
- THSD7B | c.4446T>G p.P1482= (on ENST00000272643; = p.P1480= on NM_001316349.2) | Silent (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2, varscan2
- BEX1 | c.*107_*108insTTT | 3'UTR (INS) | VAF 32/37 reads (86%) | called by mutect2, pindel, varscan2
- GTF2IRD1 | c.2811+68C>T | Intron (SNP) | VAF 87/188 reads (46%) | catalogued as rs950466267; called by muse, mutect2, varscan2
- KRT25 | c.-15G>A | 5'UTR (SNP) | VAF 21/50 reads (42%) | catalogued as rs376513001; called by muse, mutect2, varscan2
- PFKFB2 | c.85+67C>A | Intron (SNP) | VAF 56/151 reads (37%) | called by muse, mutect2, varscan2
- RBM48 | c.1017+96del | Intron (DEL) | VAF 36/76 reads (47%) | called by mutect2, varscan2
- SP140 | c.1720+52G>A | Intron (SNP) | VAF 43/100 reads (43%) | catalogued as rs1455638283; called by muse, mutect2, varscan2
- SPEF2 | c.4448-3150G>T | Intron (SNP) | VAF 112/271 reads (41%) | called by muse, mutect2, varscan2
- YTHDF2P1 | n.638C>T | RNA (SNP) | VAF 15/80 reads (19%) | catalogued as rs763020598; called by muse, mutect2, varscan2
